Somatic mutation profile of tumor specimen TCGA-QR-A6H1-01A (aliquot TCGA-QR-A6H1-01A-11D-A35D-08) from TCGA case TCGA-QR-A6H1, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 55.6 years (20,295 days).
Specimen TCGA-QR-A6H1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed704104-6e24-4ee8-924c-ec5ec1a0fccd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A6H1-10A (Blood Derived Normal), aliquot TCGA-QR-A6H1-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8eec1c0-bd9b-4792-aac3-5ccde247202a

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, Frame Shift Ins 2, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CC2D1A | c.1489C>A p.L497I | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58783201; called by muse, mutect2, varscan2
- COG2 | c.1931A>G p.H644R | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs756598605; called by muse, mutect2, varscan2
- NCKAP1 | c.1556T>C p.I519T | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.178); catalogued as rs536354356; called by muse, mutect2, varscan2
- PCED1A | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs765644056; called by muse, mutect2, varscan2
- XDH | c.43-2A>G p.X15_splice | Splice Site (SNP) | VAF 18/60 reads (30%) | catalogued as COSV65150045; called by muse, mutect2, varscan2
- ZAN | c.4346G>A p.G1449D | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as rs1194759438; called by muse, mutect2
- ZNF462 | c.2042A>G p.N681S | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs1215762227; called by muse, mutect2, varscan2
- IPPK | c.290C>G p.P97R | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAN2B1 | c.2806dup p.T936Nfs*? | Frame Shift Ins (INS) | VAF 43/127 reads (34%) | called by mutect2, pindel, varscan2
- P4HTM | c.206_207dup p.L70Tfs*40 | Frame Shift Ins (INS) | VAF 7/39 reads (18%) | called by mutect2, pindel, varscan2
- PCDHA10 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PLP1 | c.5G>A p.G2D | Missense Mutation (SNP) | VAF 69/90 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMC6 | c.2165C>T p.S722F | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- ZNF629 | c.2057A>G p.N686S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- EVC | c.180C>T p.D60= | Silent (SNP) | VAF 45/126 reads (36%) | catalogued as rs755788871, COSV53832573; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRP1B | c.12201A>G p.Q4067= | Silent (SNP) | VAF 25/62 reads (40%) | called by muse, mutect2, varscan2
- COX15 | c.*1124A>G | 3'UTR (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
